Gene-level copy-number profile of tumor specimen TCGA-AA-A004-01A from TCGA case TCGA-AA-A004, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Sigmoid colon; AJCC pathologic stage: Stage IIA; Age at diagnosis: 76.5 years (27,943 days).
Specimen TCGA-AA-A004-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-COAD.afb71bd3-d291-403b-be12-5e5a435e3809.gene_level_copy_number.v36.tsv, workflow ASCAT2 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-AA-A004-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 398 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/0657b019-496f-4665-8700-8afd79ea5f64

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 807; copy number 1: 7,120; copy number 2: 40,076; copy number 3: 5,442; copy number 4: 3,720; copy number 5: 2,656; copy number 6: 104; copy number 7: 88; copy number 8: 21; copy number 16: 191.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-AA-A004-01A-01D-A008-01): tumor purity 0.55, ploidy 2.16, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 3 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:39,309,909–39,522,852, 3 genes: AC105185.1, ADAM5, ADAM3A.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 3,060 genes in 10 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr6:37,819,727–48,952,781, 242 genes, copy number 5–16 (within-gene range 1–16) (broad region; genes not listed).
- chr8:48,710,789–88,887,573, 582 genes, copy number 5 (broad region; genes not listed).
- chr8:89,412,621–107,648,032, 332 genes, copy number 5 (broad region; genes not listed).
- chr8:107,884,494–107,884,611, 1 gene, copy number 5: RNA5SP275.
- chr8:108,378,831–126,329,538, 205 genes, copy number 5 (broad region; genes not listed).
- chr8:128,323,131–137,105,458, 97 genes, copy number 5 (broad region; genes not listed).
- chr9:60,914,407–86,488,607, 393 genes, copy number 5 (broad region; genes not listed).
- chr9:100,912,320–101,793,756, 21 genes, copy number 5: AL162395.1, GAPDHP26, PLPPR1, AL161631.1, AL359893.2, ACNATP, BAAT, TRMT112P4, AL359893.1, FYTTD1P1, MRPL50, ZNF189, ALDOB, AL353621.2, TMEM246-AS1, PGAP4, AL353621.1, RNF20, GRIN3A, PPP3R2, MTND3P4.
- chr9:111,839,828–115,402,644, 81 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr20:7,069,614–60,083,872, 1,106 genes, copy number 5–8 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 5,546. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
